Somatic mutation profile of tumor specimen C3L-02556-02 (aliquot CPT0161820011) from CPTAC case C3L-02556, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 85.7 years (31,315 days).
Specimen C3L-02556-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bafac8aa-5a4f-4e31-8dc4-a3e6d2a3b1ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02556-31 (Blood Derived Normal), aliquot CPT0162570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ecc1a53-86cd-4dc5-9952-132dd87024e7

The open-access MAF lists 82 somatic variants for this specimen: 57 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 22, Frame Shift Del 3, 5'Flank 2, Nonsense Mutation 2, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 76/358 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs5030811, CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ABCB1 | c.3084G>A p.P1028= | Splice Region (SNP) | VAF 159/844 reads (19%) | catalogued as rs2235044; called by muse, mutect2, varscan2
- DSEL | c.2602A>G p.T868A | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs1371188289; called by muse, mutect2, varscan2
- GPRC6A | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs868468535, COSV59952652; called by muse, mutect2, varscan2
- LIMK2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 93/504 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762005629; called by muse, mutect2, varscan2
- MAPKAPK5 | c.146C>A p.A49E | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73411125; called by muse, mutect2
- NEB | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 80/666 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs765569689; called by muse, mutect2, varscan2
- NEO1 | c.3873G>A p.M1291I | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs751098479; called by muse, mutect2, varscan2
- PKD1 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 141/743 reads (19%) | catalogued as CM022653; called by muse, mutect2, varscan2
- PLD3 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs148056303; called by muse, mutect2, varscan2
- PTPN11 | c.229T>G p.L77V | Missense Mutation (SNP) | VAF 96/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100692898, COSV61014921; called by muse, mutect2, varscan2
- SH3RF2 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 191/619 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1013610108; called by muse, mutect2, varscan2
- SPTA1 | c.2044C>A p.Q682K | Missense Mutation (SNP) | VAF 176/790 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV63761148; called by muse, varscan2
- STAT5B | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs760681474; called by muse, mutect2, varscan2
- USPL1 | c.2669T>G p.L890R | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1310949170; called by muse, mutect2, varscan2
- WDR81 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437244365, COSV58482005; called by muse, mutect2, varscan2
- APPBP2 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP28 | c.544-22_552del p.X182_splice (on ENST00000383472 / NM_001366230.1; = p.X23_splice on NM_001010000.3) | Splice Site (DEL) | VAF 58/336 reads (17%) | called by mutect2, pindel
- ARID2 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC183 | c.231C>A p.N77K | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CDC5L | c.1432T>G p.L478V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by mutect2, varscan2
- CELSR2 | c.3878A>G p.Y1293C | Missense Mutation (SNP) | VAF 120/514 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP76 | c.1423G>C p.V475L | Missense Mutation (SNP) | VAF 154/499 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CHRNB1 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 208/947 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CHST14 | c.790dup p.L264Pfs*7 | Frame Shift Ins (INS) | VAF 537/1875 reads (29%) | called by mutect2, pindel, varscan2
- CYP2D7 | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 163/981 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DNAH17 | c.1297A>C p.T433P | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- EPHB3 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM151A | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FCN2 | c.828T>A p.N276K | Missense Mutation (SNP) | VAF 171/851 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FKBP1C | c.36C>A p.D12E | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FLVCR1 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 368/1051 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDM5C | c.2869_2870del p.G957Cfs*6 | Frame Shift Del (DEL) | VAF 126/343 reads (37%) | called by mutect2, pindel, varscan2
- KEL | c.1079T>A p.F360Y | Missense Mutation (SNP) | VAF 146/777 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAPKAPK5 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MNT | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MTMR12 | c.1827del p.R610Efs*44 | Frame Shift Del (DEL) | VAF 109/369 reads (30%) | called by mutect2, pindel, varscan2
- NELL2 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOVA2 | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- OVCH1 | c.2447C>A p.S816* | Nonsense Mutation (SNP) | VAF 42/293 reads (14%) | called by muse, mutect2, varscan2
- PER2 | c.1861A>C p.K621Q | Missense Mutation (SNP) | VAF 533/1462 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- POMGNT1 | c.1736T>C p.I579T | Missense Mutation (SNP) | VAF 108/449 reads (24%) | PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- POMP | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PPL | c.2896C>A p.L966M | Missense Mutation (SNP) | VAF 201/1032 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PRXL2A | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- RDH5 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 220/1071 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- RNF213 | c.8723C>A p.T2908K | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC28A1 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 222/986 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by mutect2, varscan2
- SYNE1 | c.19126A>G p.S6376G (on ENST00000367255 / NM_182961.4; = p.S6305G on NM_033071.3) | Missense Mutation (SNP) | VAF 122/576 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TM9SF2 | c.1247A>C p.Y416S | Missense Mutation (SNP) | VAF 117/445 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM150C | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNC | c.1617G>C p.Q539H | Missense Mutation (SNP) | VAF 118/593 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM28 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 107/520 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TSC22D1 | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.6); called by muse, varscan2
- UGT3A1 | c.569del p.L190Cfs*2 | Frame Shift Del (DEL) | VAF 82/517 reads (16%) | called by mutect2, pindel, varscan2
- VWF | c.7705G>A p.A2569T | Missense Mutation (SNP) | VAF 139/823 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF80 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR1 | c.174G>A p.K58= | Silent (SNP) | VAF 69/395 reads (17%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.177T>A p.P59= | Silent (SNP) | VAF 93/440 reads (21%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.78G>A p.L26= | Silent (SNP) | VAF 13/300 reads (4%) | called by muse, mutect2
- CEMP1 | c.312C>T p.L104= | Silent (SNP) | VAF 131/820 reads (16%) | called by muse, mutect2, varscan2
- CEP250 | c.654C>T p.T218= | Silent (SNP) | VAF 94/390 reads (24%) | called by muse, mutect2, varscan2
- CTSL | c.12A>G p.T4= | Silent (SNP) | VAF 62/281 reads (22%) | catalogued as rs749548874; called by muse, mutect2, varscan2
- FOXK2 | c.591G>A p.L197= | Silent (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- GALT | c.1092T>C p.V364= | Silent (SNP) | VAF 117/606 reads (19%) | called by muse, mutect2, varscan2
- GPT | c.549C>T p.L183= | Silent (SNP) | VAF 207/905 reads (23%) | called by muse, mutect2, varscan2
- KLF9 | c.468A>G p.K156= | Silent (SNP) | VAF 49/224 reads (22%) | called by muse, mutect2, varscan2
- PPP1R12B | c.1089G>A p.E363= | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- PRSS53 | c.222T>C p.T74= | Silent (SNP) | VAF 163/452 reads (36%) | called by muse, mutect2, varscan2
- RNF169 | c.783G>A p.Q261= | Silent (SNP) | VAF 47/325 reads (14%) | called by muse, mutect2, varscan2
- SALL1 | c.1569T>C p.S523= | Silent (SNP) | VAF 104/287 reads (36%) | catalogued as COSV99176062; called by muse, mutect2, varscan2
- SFPQ | c.672A>C p.L224= | Silent (SNP) | VAF 71/304 reads (23%) | catalogued as rs1266667022; called by muse, mutect2, varscan2
- SHPRH | c.2100T>G p.P700= | Silent (SNP) | VAF 59/317 reads (19%) | called by muse, mutect2, varscan2
- SLC40A1 | c.93T>C p.G31= | Silent (SNP) | VAF 144/932 reads (15%) | called by muse, mutect2, varscan2
- TRIM47 | c.687C>A p.S229= | Silent (SNP) | VAF 68/382 reads (18%) | called by muse, mutect2, varscan2
- TTC9 | c.273G>A p.L91= | Silent (SNP) | VAF 76/299 reads (25%) | catalogued as rs1436843136; called by muse, mutect2, varscan2
- UBASH3A | c.1075C>T p.L359= | Silent (SNP) | VAF 68/377 reads (18%) | catalogued as rs1336348370; called by muse, mutect2, varscan2
- URGCP | c.294C>A p.I98= (on ENST00000453200 / NM_001077663.3; = p.I89= on NM_017920.4) | Silent (SNP) | VAF 110/518 reads (21%) | catalogued as COSV56249050; called by muse, mutect2, varscan2
- ZNF628 | c.2112A>C p.P704= | Silent (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500095 A>G | 5'Flank (SNP) | VAF 38/213 reads (18%) | called by muse, varscan2
- NCL | chr2:231452758 A>T | 3'Flank (SNP) | VAF 22/143 reads (15%) | called by muse, varscan2
- TMEM121B | chr22:17122581 A>G | 5'Flank (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
